Somatic mutation profile of tumor specimen TCGA-B0-4706-01A (aliquot TCGA-B0-4706-01A-01D-1501-10) from TCGA case TCGA-B0-4706, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G4; Age at diagnosis: 61.1 years (22,331 days).
Specimen TCGA-B0-4706-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 00ce81d5-e0de-4a3b-9a1e-6fbf12dca8ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-4706-11A (Solid Tissue Normal), aliquot TCGA-B0-4706-11A-02D-1501-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c2d6828a-9ac0-43b2-b476-eb5b4fc59277

The open-access MAF lists 44 somatic variants for this specimen: 35 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 8, Nonsense Mutation 4, Frame Shift Del 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTR5 | c.926A>G p.N309S | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs368018075; called by muse, mutect2, varscan2
- AMD1 | c.578A>G p.Y193C | Missense Mutation (SNP) | VAF 28/440 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.386); catalogued as rs756750412, COSV64387144; called by muse, mutect2
- ATF6B | c.1872G>A p.M624I | Missense Mutation (SNP) | VAF 77/196 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.186); catalogued as COSV64351396; called by muse, mutect2, varscan2
- COL19A1 | c.372C>A p.N124K | Missense Mutation (SNP) | VAF 115/305 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as rs772716636, COSV100506381; called by muse, mutect2, varscan2
- DGKH | c.2351C>T p.S784L | Missense Mutation (SNP) | VAF 40/164 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54929583; called by muse, mutect2, varscan2
- DKKL1 | c.363G>T p.E121D | Missense Mutation (SNP) | VAF 69/217 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.442); catalogued as rs527385357, COSV55561902; called by muse, mutect2, varscan2
- GAL3ST2 | c.277G>T p.G93C | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV51949824; called by muse, mutect2, varscan2
- GBF1 | c.412C>T p.Q138* | Nonsense Mutation (SNP) | VAF 51/154 reads (33%) | catalogued as COSV64143749; called by muse, mutect2, varscan2
- GPCPD1 | c.657A>G p.I219M | Missense Mutation (SNP) | VAF 71/237 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV66830430; called by muse, mutect2, varscan2
- IQGAP2 | c.360G>T p.M120I | Missense Mutation (SNP) | VAF 143/540 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.431); catalogued as COSV57170896; called by muse, mutect2, varscan2
- KIFBP | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.214); catalogued as COSV62555440; called by muse, mutect2, varscan2
- KLK10 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 57/182 reads (31%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs142960865; called by muse, mutect2, varscan2
- LCN12 | c.574T>C p.C192R | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); catalogued as COSV65421627; called by muse, mutect2, varscan2
- LRP1 | c.2156T>C p.F719S | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.107); catalogued as COSV54505755; called by muse, mutect2, varscan2
- MKI67 | c.1567C>G p.P523A | Missense Mutation (SNP) | VAF 145/497 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV64073450; called by muse, mutect2, varscan2
- MROH2B | c.3060C>G p.N1020K | Missense Mutation (SNP) | VAF 123/388 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as COSV68182418; called by muse, mutect2, varscan2
- MRPS5 | c.568G>T p.E190* | Nonsense Mutation (SNP) | VAF 182/548 reads (33%) | catalogued as COSV55533188; called by muse, mutect2, varscan2
- MTUS1 | c.2918C>T p.T973I (on ENST00000262102 / NM_001363061.1; = p.T139I on NM_020749.4) | Missense Mutation (SNP) | VAF 31/640 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV50552720; called by muse, mutect2
- MUC16 | c.2774G>T p.S925I | Missense Mutation (SNP) | VAF 88/292 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.635); catalogued as COSV67454763; called by muse, mutect2, varscan2
- NPNT | c.1027C>A p.P343T | Missense Mutation (SNP) | VAF 133/415 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.202); catalogued as COSV59752623; called by muse, varscan2
- NUMA1 | c.206A>G p.Q69R | Missense Mutation (SNP) | VAF 42/161 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV61184229; called by muse, mutect2
- PBRM1 | c.3839_3844del p.S1280_K1282delins* (on ENST00000296302 / NM_001366071.2; = p.S1255_K1257delins* on NM_018313.5) | Nonsense Mutation (DEL) | VAF 159/477 reads (33%) | catalogued as COSV56268139; called by mutect2, pindel, varscan2
- PKP2 | c.1861G>A p.E621K | Missense Mutation (SNP) | VAF 173/627 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as rs749196250, COSV50727558; called by muse, mutect2, varscan2
- SCAPER | c.1361T>C p.I454T | Missense Mutation (SNP) | VAF 475/1649 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57736653; called by muse, mutect2, varscan2
- SEMA3E | c.1631G>T p.C544F | Missense Mutation (SNP) | VAF 72/214 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57083814; called by muse, mutect2, varscan2
- SETD3 | c.41C>T p.T14I | Missense Mutation (SNP) | VAF 161/537 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.255); catalogued as COSV59283386; called by muse, mutect2, varscan2
- STPG3 | c.626G>A p.G209D | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.469); catalogued as COSV58024476; called by muse, mutect2, varscan2
- TBATA | c.127A>G p.I43V | Missense Mutation (SNP) | VAF 45/163 reads (28%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.028); catalogued as COSV54718160; called by muse, mutect2, varscan2
- TCF20 | c.4150G>A p.D1384N | Missense Mutation (SNP) | VAF 71/271 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV59489482; called by muse, mutect2, varscan2
- VHL | c.494T>A p.V165D | Missense Mutation (SNP) | VAF 93/209 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as HM971603, COSV56546432; called by muse, mutect2, varscan2
- ZFY | c.91C>T p.Q31* | Nonsense Mutation (SNP) | VAF 281/447 reads (63%) | catalogued as COSV50083031; called by muse, mutect2, varscan2
- ZMYM1 | c.3256T>A p.S1086T | Missense Mutation (SNP) | VAF 91/313 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.331); catalogued as COSV63251208; called by muse, mutect2, varscan2
- ZMYM1 | c.3257C>T p.S1086L | Missense Mutation (SNP) | VAF 89/309 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV63251219; called by muse, mutect2, varscan2
- NCAPG | c.1463_1464del p.K488Rfs*6 | Frame Shift Del (DEL) | VAF 71/249 reads (29%) | called by mutect2, pindel, varscan2
- SPTBN1 | c.4062del p.K1354Nfs*39 | Frame Shift Del (DEL) | VAF 92/299 reads (31%) | called by mutect2, pindel, varscan2
- AMER3 | c.1353G>A p.P451= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs755026977, COSV58465820; called by muse, mutect2, varscan2
- CTTNBP2 | c.2607T>A p.A869= | Silent (SNP) | VAF 66/220 reads (30%) | catalogued as COSV50392760; called by muse, mutect2, varscan2
- DNAJC10 | c.2070T>C p.H690= | Silent (SNP) | VAF 407/946 reads (43%) | catalogued as rs140227116; called by muse, mutect2, varscan2
- MAGEB4 | c.495C>G p.A165= | Silent (SNP) | VAF 28/46 reads (61%) | catalogued as COSV66775494; called by muse, mutect2
- SNX14 | c.36G>A p.L12= | Silent (SNP) | VAF 14/25 reads (56%) | catalogued as COSV59010673; called by muse, mutect2, varscan2
- TPRG1L | c.732C>T p.L244= | Silent (SNP) | VAF 61/181 reads (34%) | catalogued as COSV54560606; called by muse, mutect2, varscan2
- TYRP1 | c.771C>T p.V257= | Silent (SNP) | VAF 252/707 reads (36%) | catalogued as COSV66357804, COSV66357916; called by muse, mutect2, varscan2
- ZSCAN29 | c.1980T>C p.F660= | Silent (SNP) | VAF 139/516 reads (27%) | catalogued as COSV67822297; called by muse, mutect2, varscan2
- DCHS2 | n.8142G>C | RNA (SNP) | VAF 89/298 reads (30%) | catalogued as COSV61769632; called by muse, mutect2
